Surgical pathology report (de-identified scan), TCGA case TCGA-E3-A3E0, project TCGA-THCA (Thyroid Carcinoma), tissue source site Roswell Park, specimen TCGA-E3-A3E0-01A (Primary Tumor).

[page 1 of 2]
100-0-3

Carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos C73.9 lw 10/26/11

SPECIMENS:

- A. ANTERIOR NECK VEIN
- B. LEFT LOBE AND ISTHMUS
- C. COMPLETION OF THYROIDECTOMY

DIAGNOSIS:

- A. SOFT TISSUE, ANTERIOR NECK, EXCISION:
- BENIGN FIBROADIPOSE TISSUE AND BLOOD VESSELS, NO MALIGNANCY IDENTIFIED.
- B. THYROID, LEFT LOBE AND ISTHMUS, PARTIAL THYROIDECTOMY:
- PAPILLARY THYROID CARCINOMA, (2.4 x 1.5 x 1.0 CM, CONFINED TO THE THYROID GLAND).
- LYMPHOCYTIC THYROIDITIS.
- TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).
- SEE TEMPLATE.
- C. THYROID, RIGHT LOBE, COMPLETION THYROIDECTOMY:
- BENIGN THYROID WITH FOCAL LYMPHOCYTIC THYROIDITIS.
- ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

THYROID TEMPLATE

Specimen Type:	Total thyroidectomy
Tumor Site:	Left lobe
Tumor Focality:	
Tumor Size (Greatest dimension):	2.4 cm
Additional dimensions:	1.5 x 1.0 cm
Histologic Type:	Papillary carcinoma
Margins:	Margins uninvolved by carcinoma, distance of carcinoma to closest margins: 1 mm
Venous/Lymphatic Invasion:	Absent
Additional Findings:	Lymphocytic thyroiditis
Lymph Nodes (Neck Dissection):	Not done
Pathologic Stage:	pT2 N0 Mx

SPECIMEN(S):

- A. ANTERIOR NECK VEIN B. LEFT LOBE AND ISTHMUS C. COMPLETION OF THYROIDECTOMY

CLINICAL HISTORY:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

B) Left lobe and isthmus: Papillary thyroid carcinoma by Dr.
Diagnosis called to Dr. at

GROSS DESCRIPTION:

A. ANTERIOR NECK VEIN:

Received in formalin and labeled anterior neck vein are two pieces of blood vessels with attached fibrous and adipose tissue present. They measure 3.5 x 1.5 x 0.5 cm. and 5.3 x 2.4 x 0.3 cm. On sectioning no masses or lesions are seen. Representative sections are submitted in block A1.

B. LEFT LOBE AND ISTHMUS:

Received fresh and labeled as left lobe and isthmus is a portion of unoriented thyroid gland weighing 9.5 grams and measuring 4.7 x 2.5 x 1.4 cm. The capsule is inked black and the specimen is sectioned along the long axis. There is a 2.4 x 1.5 x 1 cm. nodule seen at 0.2 cm from the capsule. It has a tan granular cut surface. The remainder of the specimen is unremarkable. The specimen is submitted in toto as follows:

FSB1: frozen section of nodule

B2-B10: remainder of thyroid tissue including nodule

C. COMPLETION OF THYROIDECTOMY:

Received in formalin and labeled completion of thyroidectomy is the right lobe of the thyroid including a portion of the isthmus weighing 6 grams and measuring 3.7 x 2.9 x 1.3 cm. The right lobe of the thyroid

[page 2 of 2]
is inked black and the isthmus is inked orange. The specimen is serially sectioned and no masses or lesions are seen. The thyroid tissue is submitted in toto as follows:

C1: isthmus

C2-C5: right lobe

Gross Dictation: , ,

Gross Review: , MD, ,

Microscopic/Diagnostic Dictation: , M.D. Pathologist.

Final Review: , M.D., Pathologist

Final: , M.D., Pathologist,

Prior Ineligibility History		/

W 10/26/11

Source: NCI Genomic Data Commons file 876025cd-e53e-46dc-989a-6565fdac6cb9 (TCGA-E3-A3E0.7182D9F1-4059-4753-83EE-EB2669B1F413.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).